CCDI case PBBNVP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/d9048ac3-3b9e-4dd5-a025-c9a3e673efd8

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 12.5 years (4,555 days).

Biospecimens (3 samples)
- Sample 0DE0QN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE0R4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE0TV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
